Somatic mutation profile of tumor specimen BA2882D (aliquot aq-BA2882D) from BEATAML1.0 case 2463, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 29.5 years (10,787 days).
Specimen BA2882D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5baf7692-5670-47af-8ad3-9e42a23cca9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2327D (Solid Tissue Normal), aliquot aq-BA2327D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39881308-fcb2-4301-80e5-c055bf635726

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Frame Shift Del 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 9/150 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045586, COSV59537585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TLE3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV58167025, COSV58174440; called by muse, mutect2
- IGHV3-23 | c.32del p.V11Gfs*4 | Frame Shift Del (DEL) | VAF 29/157 reads (18%) | called by mutect2, pindel, varscan2
- KIAA1671 | c.3469G>A p.G1157S | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OGG1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PHF10 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SIX5 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2
- TONSL | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CDH20 | c.2199C>T p.A733= | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as rs1260759665, COSV99406470; called by muse, mutect2, varscan2
- FER1L4 | n.2827G>A | RNA (SNP) | VAF 25/65 reads (38%) | catalogued as rs924737567; called by muse, mutect2, varscan2
- GRM4 | c.520-11571del | Intron (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- SLC22A5 | c.497+24A>G | Intron (SNP) | VAF 59/267 reads (22%) | called by muse, mutect2, varscan2
